Somatic mutation profile of tumor specimen BA2614D (aliquot aq-BA2614D) from BEATAML1.0 case 2095, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.7 years (20,346 days).
Specimen BA2614D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50a33460-fd98-4721-876d-83622d6073a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2990D (Solid Tissue Normal), aliquot aq-BA2990D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2f1ecf2-2e54-4a7b-9c33-4e31bf62daaa

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 2, Frame Shift Ins 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 27/73 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C1QA | c.639C>A p.D213E | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.887); catalogued as rs961087888; called by muse, mutect2
- CDHR1 | c.1432G>A p.V478I | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs756095042; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCCTG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 20/61 reads (33%) | catalogued as rs1554138189, COSV51543231, COSV51545499, COSV51554041, COSV51557774, COSV51563665; called by mutect2, pindel, varscan2
- PSG7 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.999); catalogued as rs768499882, COSV101343342; called by muse, mutect2, varscan2
- TET2 | c.4501C>T p.Q1501* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV54422236; called by mutect2, varscan2
- THSD7B | c.3983G>A p.R1328H (on ENST00000272643; = p.R1326H on NM_001316349.2) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746708463; called by muse, varscan2
- TMEM132C | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV59436836; called by muse, mutect2, varscan2
- WIPI1 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as rs765767251; called by muse, mutect2, varscan2
- ADM2 | c.205C>G p.Q69E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ARSJ | c.1069G>T p.G357C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2
- CEBPA | c.911A>C p.K304T | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEBPA | c.117del p.A40Rfs*120 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel
- COL7A1 | c.4189G>A p.A1397T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAJC11 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- NCKAP1 | c.756C>G p.Y252* | Nonsense Mutation (SNP) | VAF 39/119 reads (33%) | called by muse, mutect2, varscan2
- OR5D13 | c.626A>T p.E209V | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- BTBD11 | c.2574G>A p.T858= (on ENST00000280758 / NM_001018072.2; = p.T395= on NM_001017523.2) | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs1037491804, COSV55021373; called by muse, mutect2, varscan2
- PNCK | c.990C>T p.H330= (on ENST00000340888 / NM_001366975.1; = p.H413= on NM_001039582.3) | Silent (SNP) | VAF 50/120 reads (42%) | called by muse, mutect2, varscan2
- TFAM | c.735G>A p.E245= | Silent (SNP) | VAF 68/188 reads (36%) | catalogued as rs771875301; called by muse, mutect2, varscan2
- COASY | c.916-69C>T | Intron (SNP) | VAF 7/23 reads (30%) | catalogued as rs757515358; called by muse, varscan2
